Somatic mutation profile of tumor specimen TCGA-S9-A7R3-01A (aliquot TCGA-S9-A7R3-01A-11D-A34J-08) from TCGA case TCGA-S9-A7R3, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 28.3 years (10,342 days).
Specimen TCGA-S9-A7R3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22437324-2d68-4e96-a9e6-586724be3377.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A7R3-10A (Blood Derived Normal), aliquot TCGA-S9-A7R3-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ebfbf8a2-dc49-46f5-af86-93b827867475

The open-access MAF lists 27 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 4, Nonsense Mutation 1, 5'UTR 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 64/156 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 39/46 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ART1 | c.196C>T p.H66Y | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99167235; called by muse, mutect2, varscan2
- CBLN2 | c.620T>A p.L207H | Missense Mutation (SNP) | VAF 96/208 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99504566; called by muse, mutect2, varscan2
- CCT8L2 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 64/149 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100743025; called by muse, mutect2, varscan2
- CFAP52 | c.683A>C p.D228A | Missense Mutation (SNP) | VAF 159/378 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100235499; called by muse, mutect2, varscan2
- DCBLD1 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99757952; called by muse, mutect2, varscan2
- ERC1 | c.451A>G p.I151V | Missense Mutation (SNP) | VAF 8/193 reads (4%) | SIFT tolerated (0.77); PolyPhen benign (0.028); catalogued as rs1320437919, COSV100706570; called by muse, mutect2
- FGA | c.515A>G p.D172G | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100120613; called by muse, mutect2, varscan2
- HCFC1 | c.70G>T p.G24C | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100129698, COSV60077686; called by muse, mutect2
- IFNA21 | c.305A>G p.Q102R | Missense Mutation (SNP) | VAF 48/233 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.102); catalogued as COSV101207437; called by muse, mutect2, varscan2
- LIPE | c.616T>C p.F206L | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.022); catalogued as COSV99734350; called by muse, mutect2, varscan2
- MRPL50 | c.358A>G p.M120V | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.284); catalogued as rs763331478, COSV100879822; called by muse, mutect2, varscan2
- NDST4 | c.1053G>C p.K351N | Missense Mutation (SNP) | VAF 89/248 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99997490; called by muse, mutect2, varscan2
- PDCD11 | c.2060A>G p.D687G | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100874402; called by muse, mutect2, varscan2
- PRMT8 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); catalogued as rs766069538, COSV54212649; called by muse, mutect2, varscan2
- SCN10A | c.4363C>A p.Q1455K | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101479496; called by muse, mutect2, varscan2
- TANC2 | c.3194G>A p.R1065H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs750081650, COSV101267645; called by mutect2, varscan2
- TDRD7 | c.34C>T p.R12* | Nonsense Mutation (SNP) | VAF 34/99 reads (34%) | catalogued as rs781440085, COSV100795773; called by muse, mutect2, varscan2
- ZNF280C | c.523C>T p.H175Y | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.296); catalogued as COSV100921262; called by muse, mutect2, varscan2
- C21orf91 | c.106del p.C36Vfs*4 | Frame Shift Del (DEL) | VAF 49/173 reads (28%) | called by mutect2, pindel, varscan2
- PPAN-P2RY11 | c.1368_1370del p.V457del | In Frame Del (DEL) | VAF 14/94 reads (15%) | called by pindel, varscan2
- DNAAF6 | c.186T>C p.G62= | Silent (SNP) | VAF 43/166 reads (26%) | catalogued as COSV100314569; called by muse, mutect2, varscan2
- FCHO2 | c.2349A>G p.V783= | Silent (SNP) | VAF 50/190 reads (26%) | catalogued as COSV100530987; called by muse, mutect2, varscan2
- IRAK1 | c.1062C>T p.P354= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as COSV100318409; called by muse, mutect2, varscan2
- MYO5B | c.4638G>A p.T1546= | Silent (SNP) | VAF 89/252 reads (35%) | catalogued as rs748616963, COSV53219575; called by muse, mutect2, varscan2
- NINJ2 | c.-120C>A | 5'UTR (SNP) | VAF 22/164 reads (13%) | catalogued as COSV100523293; called by muse, mutect2, varscan2
